Surgical pathology report (de-identified scan), TCGA case TCGA-A6-6140, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-6140-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Transverse colostomy
- B. Omental lymph node
- C. Transverse and descending colon includes site of (procurement) colostomy

CLINICAL NOTES

PRE-OP DIAGNOSIS: Cancer splenic flexure.

GROSS DESCRIPTION

- A. [The] Specimen is received unfixed labeled "transverse colostomy" and consists of a colostomy takedown specimen measuring 6 x 4.5 x 3 cm. On cut section, the mucosal surface is tan with some focal red discoloration near the skin margin. Sections after fixation.
- B. Specimen is received in formalin labeled "omental lymph node" and consists of a yellow piece of tissue measuring 0.9 x 0.4 x 0.5 cm.
- C. The specimen is received unfixed labeled "transverse and descending colon" and consists of two separate segments of large bowel. One segment has stapled margins and measures 11.5 x approximately 4 cm in diameter. This segment has a central area of induration and narrowing on the serosal surface. The abnormal area is 3 cm from the nearest stapled margin. There is abundant pericolic fat and the entire specimen is up to 15 cm in diameter. The other segment of bowel has stapled margins and measures 10 cm in length and 3.5 cm in diameter. It has adjacent pericolic fat and omentum and this portion of the specimen is up to 21 cm in diameter. There is a firm area that appears to be an omental fat that measures 3 cm in greatest dimension. On cut section, the omental lesion is tan-green and measures 1.5 cm in greatest dimension. Segments of bowel are open with single incisions on the antimesenteric surface. There is a fungating tumor in the descending colon that has a polypoid appearance and appears to be circumferential. It measures 6.5 x 5.5 x approximately 1 cm. Portions of the specimen are taken for research purposes. Sections after fixation and clearing.

Block summary: 1,2 transverse colon margins of resection; 3 transverse colon; 4 omentum; 5-8 transverse colon lymph nodes; 9,10 descending colon margins; 11 cobblestone mucosa; 12-15 tumor; 16-26 pericolic lymph nodes.

MICROSCOPIC DESCRIPTION

- A. Benign reactive changes are seen.
- B. A single lymph node is negative for malignancy.
- C.
- Tumor type: Colonic adenocarcinoma
- Tumor grade: 1 of 3
- Tumor size: 6.5
- Distance to nearest margin: 3
- Level of penetration: Carcinoma penetrates into pericolic soft tissue
- Margins of resection: Negative for malignancy

[page 2 of 2]
[REDACTED]

Vascular invasion: Absent
Host response: Mild chronic inflammation, focally Crohn's like
Attached lymph nodes: There is no evidence of malignancy in any of
34 lymph nodes in the descending colon or
12 lymph nodes in the transverse colon.
Non-lymph node pericolonic tumor: Absent
pTNM Stage: T3 N0
Other findings: Omental fat necrosis. Transverse colon unremarkable. Cobblestone mucosa in the descending colon is lymphoid hyperplasia.

2,3,5

DIAGNOSIS

- A. Transverse colon colostomy, takedown: Benign reactive changes
- B. Omental lymph node, biopsy: A single lymph node is negative for malignancy
- C. Colon, transverse and descending, resection:
- Well-differentiated colonic adenocarcinoma of the descending colon.
- Note: The margins of resection are negative for malignancy.
- There is no evidence of malignancy in any of 12 transverse colon lymph nodes or 34 descending colon lymph nodes.
- [REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file 294fcff1-9a3c-4dfd-a6cc-77fb3e72be57 (TCGA-A6-6140.72F5199D-0B09-44B9-81FD-67A71F21F2AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).